Surgical pathology report (de-identified scan), TCGA case TCGA-AP-A0LE, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site MSKCC, specimen TCGA-AP-A0LE-01A (Primary Tumor).

[page 1 of 2]
TSS Name/#:

Specimens Submitted:

- 1: SP: Uterus, cervix, bilateral fallopian tubes ovaries
- 2: SP: Lt. obturator nodes
- 3: SP: Lt. common iliac nodes
- 4: SP: Lt. para-aortic nodes
- 5: SP: Rt. para-aortic nodes
- 6: SP: Rt. common iliac nodes
- 7: SP: Rt. external iliac nodes
- 8: SP: Rt. obturator nodes

DIAGNOSIS:

- 1) UTERUS, CERVIX, BILATERAL FALLOPIAN TUBES AND OVARIES; TOTAL ABDOMINAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY:
- ADENOCARCINOMA OF ENDOMETRIUM, ENDOMETRIOID TYPE, NOS, FIGO GRADE II (6-50% SOLID GROWTH), NUCLEAR GRADE 3.
- MULTIPLE MICROSCOPIC FOCI OF MICROINVASION.
- THE MAXIMAL THICKNESS OF MYOMETRIAL INVASION IS 1.0 MM.
- THE THICKNESS OF THE MYOMETRIUM IN THE AREA OF MAXIMAL TUMOR INVASION IS 19.0 MM.
- NO ENDOCERVICAL INVASION IS IDENTIFIED.
- NO VASCULAR INVASION IS IDENTIFIED.
- THE ENDOMETRIUM SHOWS COMPLEX HYPERPLASIA WITH ATYPYA IN A BACKGROUND OF PROLIFERATIVE ENDOMETRIUM.
- THE MYOMETRIUM SHOWS ADENOMYOSIS AND LEIOMYOMAS.
- THE RIGHT OVARY SHOWS AN EPITHELIAL INCLUSION CYST.
- ALL OTHER ADNEXAE ARE UNREMARKABLE.
- THE PARAMETRIA ARE NEGATIVE.

NOTE: DR. [REDACTED] HAS SEEN THIS CASE AND CONCURS.

- 2) LYMPH NODES, LEFT OBTURATOR; EXCISION:
- FIVE BENIGN LYMPH NODES (0/5).
- 3) LYMPH NODES, LEFT COMMON ILIAC; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
- 4) LYMPH NODES, LEFT PARA-AORTIC; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).

** Continued on next page **

100-0-3
adenocarcinoma, endometrioid, nos 8380/3
Site: endometrium C54.1 w 57.1"

		w 57.1"

[page 2 of 2]
- 5) LYMPH NODES, RIGHT PARA-AORTIC; EXCISION:
- FOUR BENIGN LYMPH NODES (0/4).
- 6) LYMPH NODES, RIGHT COMMON ILIAC; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
- 7) LYMPH NODES, RIGHT EXTERNAL ILIAC; EXCISION:
- FIVE BENIGN LYMPH NODES (0/5).
- 8) LYMPH NODES, RIGHT OBTURATOR; EXCISION:
- SEVEN BENIGN LYMPH NODES (0/7).

** Report Electronically Signed Out **

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION
OF THE SLIDES (AND/OR OTHER
MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Source: NCI Genomic Data Commons file 64f757ab-3731-4fa7-a71e-2f76d0cdcc0f (TCGA-AP-A0LE.3EA84930-6B34-43B8-A5A8-3D2B3754155F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).